Somatic mutation profile of tumor specimen TCGA-XF-AAMG-01A (aliquot TCGA-XF-AAMG-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 49.3 years (18,021 days).
Specimen TCGA-XF-AAMG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12d76009-b8c0-40b1-a8b4-60e02377a15e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMG-10A (Blood Derived Normal), aliquot TCGA-XF-AAMG-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/276153bd-0b3e-4e74-a527-761cc281ea63

The open-access MAF lists 1,082 somatic variants for this specimen: 807 protein-altering or splice-affecting, 254 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 710, Silent 254, Nonsense Mutation 64, Splice Site 21, Intron 12, 3'UTR 5, Frame Shift Del 4, Splice Region 3, Nonstop Mutation 2, RNA 2, Frame Shift Ins 2, 3'Flank 1.

Variants (750 of 1,082; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1531-1G>T p.X511_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | hotspot (GDC flag); catalogued as COSV59536648, COSV59540425, COSV59548961; called by muse, mutect2, varscan2
- LARS2 | c.*653C>T | 3'UTR (SNP) | VAF 7/122 reads (6%) | catalogued as rs879255408, COSV55531992; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/40 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- A2ML1 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55295236; called by muse, mutect2, varscan2
- AARD | c.447T>G p.D149E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV65600185; called by muse, varscan2
- ABCB10 | c.2048G>A p.R683K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV60621962; called by muse, mutect2, varscan2
- ABCD2 | c.2003+1G>T p.X668_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100429091, COSV58053569; called by muse, mutect2, varscan2
- ABCF3 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs775078652, COSV53049389; called by muse, mutect2, varscan2
- ACAP3 | c.279+1G>A p.X93_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV61222902; called by muse, mutect2, varscan2
- ACD | c.1061C>G p.S354C (on ENST00000620338; = p.S265C on NM_022914.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); catalogued as COSV54669250; called by muse, mutect2, varscan2
- ACTL7A | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs147436702; called by muse, mutect2, varscan2
- ADAMTS18 | c.3556C>G p.P1186A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV51409936, COSV51420128; called by muse, mutect2, varscan2
- ADAMTS18 | c.3528C>G p.F1176L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV51420131; called by muse, mutect2, varscan2
- ADCY8 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53894881, COSV53907491, COSV53918807; called by muse, mutect2
- ADD1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as rs556312325, COSV53266719; called by muse, mutect2, varscan2
- ADPGK | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61174679; called by muse, mutect2, varscan2
- AFAP1L2 | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58417232; called by muse, mutect2, varscan2
- AFDN | c.4732G>A p.E1578K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); catalogued as rs201932853, COSV60050838; called by muse, mutect2, varscan2
- AGL | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV54056089; called by muse, mutect2, varscan2
- AGO3 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV55795570; called by muse, mutect2, varscan2
- AGR2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as COSV68597168; called by muse, mutect2, varscan2
- AIP | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54161436; called by muse, mutect2, varscan2
- AK7 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV50877371; called by muse, mutect2, varscan2
- AKAP1 | c.2605C>G p.L869V | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61806156, COSV61806525; called by muse, varscan2
- AKAP10 | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV56732377; called by muse, mutect2, varscan2
- AKAP9 | c.3574C>G p.Q1192E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV62353386; called by muse, mutect2, varscan2
- AKAP9 | c.3834C>G p.S1278R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV62348823, COSV62353401; called by muse, mutect2, varscan2
- AKIRIN1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV65910250; called by muse, mutect2, varscan2
- ALK | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs925802421, COSV66581369, COSV66582899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.8290C>G p.L2764V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52516672, COSV52521873; called by muse, mutect2, varscan2
- ALMS1 | c.8965C>G p.Q2989E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV52516683; called by muse, mutect2, varscan2
- ALMS1 | c.9275C>G p.S3092W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52516695; called by muse, mutect2, varscan2
- ALMS1 | c.9514G>C p.E3172Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as CM150666, COSV52516715; called by muse, mutect2, varscan2
- ALPK1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV51589073; called by muse, mutect2, varscan2
- ALYREF | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs752276341, COSV58668895; called by muse, mutect2, varscan2
- ALYREF | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV58668903; called by muse, mutect2, varscan2
- AMIGO3 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57539471, COSV57539601; called by muse, mutect2, varscan2
- AMN | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1372015113, COSV54487457; called by muse, mutect2
- AMPD2 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV56649481; called by muse, mutect2, varscan2
- AMTN | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV59489642; called by muse, mutect2, varscan2
- ANAPC4 | c.1898G>C p.R633T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59545419; called by muse, mutect2, varscan2
- ANAPC5 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201038764, COSV55844196; called by muse, mutect2, varscan2
- ANK3 | c.3112G>A p.E1038K (on ENST00000280772 / NM_001320874.2; = p.E172K on NM_001149.3) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55046407; called by muse, mutect2, varscan2
- ANKRD34A | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV60160409, COSV60160521; called by muse, mutect2, varscan2
- ANXA9 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 59/86 reads (69%) | catalogued as COSV100929104, COSV100929183; called by muse, mutect2, varscan2
- AP4M1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57997946; called by muse, mutect2, varscan2
- APCDD1 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62372781, COSV62372899; called by muse, mutect2, varscan2
- APLP1 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99697708; called by muse, mutect2
- APOBEC4 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1219151656, COSV58018181; called by muse, mutect2, varscan2
- APOH | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs141252899; called by muse, mutect2, varscan2
- ARHGAP20 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV52816029; called by muse, mutect2, varscan2
- ARHGAP32 | c.5200G>A p.D1734N (on ENST00000310343 / NM_001378025.1; = p.D1385N on NM_014715.4) | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV59852821; called by muse, mutect2, varscan2
- ARHGAP35 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178800275, COSV68333846; called by muse, mutect2, varscan2
- ARMC3 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53064992; called by muse, mutect2, varscan2
- ARRDC3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs935998830, COSV54365985; called by muse, mutect2, varscan2
- ASB3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs1359465505, COSV55078236; called by muse, mutect2, varscan2
- ASB6 | c.1265G>C p.*422Sext*1 | Nonstop Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV52965700, COSV99475727; called by muse, mutect2, varscan2
- ASB7 | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV58404222; called by muse, mutect2, varscan2
- ASIC5 | c.1416C>G p.Y472* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101611142; called by muse, varscan2
- ASTE1 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as COSV53909579; called by muse, mutect2, varscan2
- ASTN1 | c.3598G>C p.E1200Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV62500077, COSV62501581; called by muse, mutect2, varscan2
- ATAD5 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs757101118, COSV58977041; called by muse, mutect2, varscan2
- ATAD5 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58977063; called by muse, mutect2, varscan2
- ATG13 | c.1468G>C p.E490Q (on ENST00000359513 / NM_001346321.1; = p.E453Q on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV56321159; called by muse, mutect2, varscan2
- ATM | c.3826C>T p.Q1276* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as COSV99589828; called by muse, mutect2, varscan2
- ATP9A | c.1921A>T p.M641L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV58769777; called by muse, mutect2, varscan2
- ATP9B | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV56957342; called by muse, mutect2, varscan2
- B3GNT2 | c.347T>A p.F116Y | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57345349; called by muse, mutect2, varscan2
- BBOX1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 129/187 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV54190799, COSV54192226; called by muse, mutect2, varscan2
- BCHE | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100011955, COSV52259964; called by muse, mutect2
- BCL9 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV99325223; called by muse, mutect2, varscan2
- BDKRB2 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as COSV100021300, COSV60016124; called by muse, varscan2
- BRCA1 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58788540, COSV58788661; called by muse, mutect2, varscan2
- BRSK1 | c.858-1G>C p.X286_splice | Splice Site (SNP) | VAF 33/119 reads (28%) | catalogued as COSV58668459; called by muse, mutect2, varscan2
- BSN | c.5438G>C p.R1813T | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1373229756, COSV56523849; called by muse, mutect2, varscan2
- BTN1A1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 122/164 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs765523860, COSV55068781; called by muse, mutect2, varscan2
- C19orf53 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs183989129, COSV55605987; called by muse, mutect2, varscan2
- C5 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56330449; called by muse, mutect2
- C6orf47 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100789017, COSV63264161; called by muse, mutect2
- C6orf89 | c.610G>C p.E204Q (on ENST00000373685; = p.E211Q on NM_152734.4) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV62102679; called by muse, mutect2, varscan2
- C7 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100495315, COSV57481890; called by muse, mutect2, varscan2
- CA5B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs766858791, COSV59417187; called by muse, mutect2, varscan2
- CAAP1 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV61701271; called by muse, mutect2, varscan2
- CABS1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV56734159; called by muse, mutect2, varscan2
- CACNA2D1 | c.3247T>A p.Y1083N (on ENST00000356253 / NM_001366867.1; = p.Y1071N on NM_000722.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100666086, COSV100666716; called by muse, mutect2
- CAD | c.5785G>T p.V1929F | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53025880, COSV53029997; called by muse, mutect2, varscan2
- CAMK2A | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV62247051, COSV62247885; called by muse, mutect2, varscan2
- CAMK4 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs751581823, COSV56667213; called by muse, mutect2, varscan2
- CAP1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61224066; called by muse, mutect2, varscan2
- CAPRIN2 | c.1785G>T p.V595= | Splice Region (SNP) | VAF 15/54 reads (28%) | catalogued as rs374376176, COSV51834224; called by muse, mutect2, varscan2
- CAPRIN2 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1565735543, COSV51834244; called by muse, mutect2, varscan2
- CARD8 | c.841C>T p.P281S (on ENST00000651546 / NM_001184900.3; = p.P231S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62874561; called by muse, mutect2, varscan2
- CARNS1 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV100322025; called by muse, mutect2, varscan2
- CATSPERD | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 34/53 reads (64%) | catalogued as COSV101062597, COSV67534240; called by muse, mutect2, varscan2
- CATSPERG | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs376077607; called by muse, mutect2, varscan2
- CC2D1B | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV52561822; called by muse, mutect2, varscan2
- CCDC141 | c.4283T>C p.L1428S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55378506; called by muse, mutect2, varscan2
- CCDC85A | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs1271576107, COSV68153989; called by muse, mutect2, varscan2
- CCDC88B | c.4369C>G p.R1457G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99590082; called by muse, mutect2
- CCN3 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV52384730; called by muse, mutect2, varscan2
- CCNB3 | c.3402C>A p.F1134L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52077379; called by muse, mutect2, varscan2
- CCZ1B | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV100367871; called by mutect2, varscan2
- CD1D | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV63809545; called by muse, mutect2, varscan2
- CD1E | c.1134G>C p.K378N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV63772131; called by muse, mutect2, varscan2
- CD40LG | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 186/209 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs200840715, COSV65698863; called by muse, mutect2, varscan2
- CDC16 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1254261915, COSV52960897; called by muse, mutect2, varscan2
- CDCA8 | c.842G>C p.*281Sext*10 | Nonstop Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100523621; called by muse, mutect2, varscan2
- CDH3 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV50564139; called by muse, mutect2, varscan2
- CDH8 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV54885551; called by muse, mutect2, varscan2
- CDH9 | c.2225G>C p.G742A | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50360189, COSV99141426; called by muse, mutect2, varscan2
- CDHR2 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV56142536; called by muse, mutect2
- CDIN1 | c.760G>C p.E254Q (on ENST00000437989; = p.E156Q on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV100589839; called by muse, mutect2
- CDK12 | c.1841C>G p.S614C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV71001937; called by muse, mutect2, varscan2
- CDK4 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV56986004; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2074C>G p.P692A | Missense Mutation (SNP) | VAF 94/114 reads (82%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV62576638; called by muse, mutect2, varscan2
- CDR2 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs145515892; called by muse, mutect2, varscan2
- CELA2B | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as COSV101025803; called by muse, mutect2
- CEP104 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65517961; called by muse, mutect2, varscan2
- CEP192 | c.6533C>T p.P2178L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752068576, COSV58068137; called by muse, mutect2, varscan2
- CEP250 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs147660483; called by muse, mutect2, varscan2
- CEP55 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65185551; called by muse, mutect2, varscan2
- CEP55 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs1267115343, COSV65185558; called by muse, varscan2
- CEP83 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781589454, COSV100352674, COSV60406717; called by muse, mutect2, varscan2
- CEP89 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59862860, COSV59866359; called by muse, mutect2, varscan2
- CERS2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.096); catalogued as COSV54989137, COSV54989206; called by muse, mutect2, varscan2
- CFAP251 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99945675; called by muse, mutect2, varscan2
- CFAP57 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1367523123, COSV52540935; called by muse, mutect2, varscan2
- CHD8 | c.5747C>A p.P1916H (on ENST00000646647 / NM_001170629.2; = p.P1637H on NM_020920.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1368776289, COSV63037103, COSV63037214; called by muse, mutect2, varscan2
- CIAO1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754584475, COSV51497735; called by muse, mutect2, varscan2
- CIITA | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.068); catalogued as rs1227136871, COSV60860151; called by muse, varscan2
- CILP2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs566626433, COSV52278121; called by muse, mutect2, varscan2
- CIP2A | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV55420289; called by muse, mutect2, varscan2
- CIR1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV59597106; called by muse, mutect2, varscan2
- CKMT2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV54174422; called by muse, mutect2, varscan2
- CLCA4 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55369908; called by muse, mutect2, varscan2
- CLCN2 | c.2068del p.E690Rfs*6 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | catalogued as rs765672654; called by mutect2, pindel, varscan2
- CLEC4F | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV55480583; called by muse, mutect2, varscan2
- CLIP4 | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV60748293, COSV60750913; called by muse, mutect2, varscan2
- CLTCL1 | c.3607G>A p.D1203N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV54235688, COSV54237174; called by muse, mutect2, varscan2
- CLVS1 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.067); catalogued as COSV57977827, COSV57979643; called by muse, mutect2, varscan2
- CNPY4 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV53542725, COSV53542966; called by muse, mutect2, varscan2
- CNTNAP5 | c.2370G>A p.W790* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV101443625; called by muse, mutect2, varscan2
- COBLL1 | c.3245C>T p.S1082L (on ENST00000392717; = p.S1044L on NM_014900.5) | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52072789; called by muse, mutect2, varscan2
- COL11A1 | c.5344G>C p.D1782H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62190669; called by muse, mutect2, varscan2
- COL11A1 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62184870, COSV62190676; called by muse, mutect2, varscan2
- COL5A2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66409657; called by muse, mutect2, varscan2
- COPE | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53231495, COSV53232648; called by muse, mutect2, varscan2
- COX6A1 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs767207473, COSV57569438, COSV57569488, COSV57569746; called by muse, mutect2, varscan2
- CPEB1 | c.1081C>A p.P361T (on ENST00000617958; = p.P301T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV55620401; called by muse, mutect2, varscan2
- CR2 | c.2749G>T p.D917Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV65508833; called by muse, mutect2, varscan2
- CREBZF | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99476308; called by muse, mutect2, varscan2
- CRYM | c.227T>C p.L76S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54832429; called by muse, mutect2, varscan2
- CSMD1 | c.1809G>T p.E603D (on ENST00000520002; = p.E602D on NM_033225.6) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59284513; called by muse, mutect2
- CSMD3 | c.8626G>T p.G2876C (on ENST00000297405 / NM_001363185.1; = p.G2707C on NM_052900.3) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52258897; called by muse, mutect2, varscan2
- CSNK1G3 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100631540; called by muse, mutect2, varscan2
- CST11 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs373640629; called by muse, mutect2, varscan2
- CSTA | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV52612627; called by muse, mutect2, varscan2
- CTAGE15 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs1373520108, COSV101372155; called by muse, mutect2, varscan2
- CTCF | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50491934, COSV99865100; called by muse, mutect2, varscan2
- CTNND2 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.952); catalogued as COSV58909584; called by muse, mutect2, varscan2
- CUBN | c.6926G>A p.G2309E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as rs762180282, COSV64722586; called by muse, mutect2, varscan2
- DCBLD2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV100471367, COSV58791866; called by muse, mutect2, varscan2
- DCDC1 | c.3082G>C p.E1028Q (on ENST00000597505 / NM_001367979.1; = p.E135Q on NM_020869.3) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1413004855, COSV104410466, COSV60306168, COSV60309790; called by muse, mutect2, varscan2
- DDB2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.71); catalogued as COSV57039974; called by muse, varscan2
- DEPTOR | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53819210; called by muse, mutect2, varscan2
- DHX33 | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56580159; called by muse, mutect2, varscan2
- DHX36 | c.471C>G p.I157M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV57675376; called by muse, mutect2, varscan2
- DHX37 | c.3166G>C p.E1056Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.222); catalogued as COSV58137330; called by muse, mutect2, varscan2
- DIABLO | c.205G>A p.E69K (on ENST00000443649 / NM_001278303.1; = p.E142K on NM_019887.6) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV57337053; called by muse, mutect2, varscan2
- DIDO1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs762869147, COSV56629938; called by muse, mutect2, varscan2
- DIP2C | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV55170478; called by muse, mutect2, varscan2
- DLG2 | c.228A>T p.Q76H (on ENST00000650630 / NM_001351274.2; = p.Q39H on NM_001142699.3) | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65854270, COSV65857435; called by muse, mutect2
- DLGAP4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs529565051, COSV59414419; called by muse, mutect2, varscan2
- DMRT1 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs752292615, COSV66523180; called by muse, mutect2, varscan2
- DMXL1 | c.7813C>T p.Q2605* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100224085; called by muse, mutect2, varscan2
- DNA2 | c.1091C>A p.S364* | Nonsense Mutation (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100622598; called by muse, mutect2, varscan2
- DNAAF5 | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV52419503; called by muse, mutect2
- DNAH11 | c.4633C>T p.H1545Y | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as COSV60969618, COSV60985006; called by muse, mutect2, varscan2
- DNAH11 | c.10081G>A p.E3361K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV60969628; called by mutect2, varscan2
- DNAH17 | c.10670G>C p.G3557A | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67758776; called by muse, mutect2, varscan2
- DNAH17 | c.9496G>A p.A3166T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs147019486; called by muse, mutect2, varscan2
- DNAH3 | c.7603A>T p.R2535W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54538383; called by muse, mutect2, varscan2
- DNAH8 | c.5286G>C p.Q1762H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV59430629; called by muse, mutect2, varscan2
- DNAH9 | c.6196G>A p.E2066K | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52364906; called by muse, mutect2, varscan2
- DNAI3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs747256885, COSV54004677; called by muse, mutect2, varscan2
- DNAJB2 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV60677557; called by muse, mutect2, varscan2
- DNAJC13 | c.4236C>G p.F1412L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV53454919; called by muse, mutect2, varscan2
- DNHD1 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 81/94 reads (86%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54440948; called by muse, mutect2, varscan2
- DOCK7 | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV52015264; called by muse, mutect2, varscan2
- DOCK8 | c.5200C>T p.Q1734* | Nonsense Mutation (SNP) | VAF 45/49 reads (92%) | catalogued as COSV101209942; called by muse, mutect2, varscan2
- DONSON | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51678714; called by muse, mutect2, varscan2
- DOP1B | c.836C>G p.S279* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV101215452; called by muse, mutect2, varscan2
- DPP4 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.238); catalogued as rs1235328602, COSV62108520; called by muse, mutect2, varscan2
- DPY19L3 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60474877, COSV60478799; called by muse, mutect2, varscan2
- DRP2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1338079656, COSV65811200; called by muse, mutect2, varscan2
- DZANK1 | c.627C>G p.L209= (on ENST00000262547 / NM_001099407.1; = p.L10= on NM_018152.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52754688; called by muse, mutect2, varscan2
- E2F7 | c.871A>C p.S291R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59742146; called by muse, mutect2, varscan2
- E2F8 | c.1851G>C p.K617N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51465138; called by muse, mutect2, varscan2
- EBNA1BP2 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV52540918; called by muse, mutect2, varscan2
- EDIL3 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344642830, COSV56911168; called by muse, mutect2, varscan2
- EDNRB | c.1194G>C p.Q398H (on ENST00000377211 / NM_001201397.1; = p.Q308H on NM_000115.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV57526029; called by muse, mutect2, varscan2
- EFCAB6 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs752435294, COSV53068447; called by muse, mutect2, varscan2
- EFHB | c.1230T>G p.F410L | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55551208; called by muse, mutect2, varscan2
- EFHC2 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69554780; called by muse, mutect2
- EGR3 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1205883514, COSV57834169; called by muse, mutect2, varscan2
- EIF3D | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV53403707, COSV53404516; called by muse, mutect2, varscan2
- EIF3E | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55204711; called by muse, mutect2, varscan2
- EIF4B | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.849); catalogued as COSV50405685; called by muse, mutect2, varscan2
- EIF4G1 | c.4054G>A p.G1352R (on ENST00000346169 / NM_198241.3; = p.G1157R on NM_004953.5) | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59992003; called by muse, mutect2, varscan2
- ELAVL1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60967875; called by muse, mutect2, varscan2
- ELAVL4 | c.1097G>C p.R366T | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63915618, COSV63917996; called by muse, mutect2, varscan2
- ELK4 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV56985767, COSV99222290; called by muse, mutect2, varscan2
- ELP3 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as COSV56460631; called by muse, mutect2, varscan2
- EMID1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV61830065; called by muse, mutect2, varscan2
- EPB41L2 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61357605; called by muse, mutect2, varscan2
- EPG5 | c.7234G>C p.E2412Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56353456; called by muse, mutect2, varscan2
- EPHB6 | c.2653C>G p.P885A | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV63892850; called by muse, mutect2, varscan2
- EPS15 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs762173438, COSV65544285; called by muse, mutect2, varscan2
- EPYC | c.341-1G>C p.X114_splice | Splice Site (SNP) | VAF 5/54 reads (9%) | catalogued as COSV53803068, COSV99664686; called by muse, mutect2
- ERCC1 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV50004948; called by muse, mutect2, varscan2
- ERCC2 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67264512; called by muse, mutect2
- ERCC3 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs746827111, COSV53427374; called by muse, mutect2, varscan2
- ERCC5 | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57281286; called by muse, mutect2
- ERN2 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55623453; called by muse, mutect2, varscan2
- ERP29 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1464192555, COSV55674157; called by muse, mutect2, varscan2
- ERP29 | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.31); catalogued as COSV55674164; called by muse, mutect2, varscan2
- EYA3 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV65817298; called by muse, mutect2, varscan2
- FAM120C | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557122168, COSV60261028; called by muse, mutect2, varscan2
- FAM174A | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 30/50 reads (60%) | catalogued as rs534257601, COSV100444465, COSV57062147; called by muse, mutect2, varscan2
- FAM24A | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV64406084; called by muse, mutect2, varscan2
- FAM3A | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59194769; called by muse, mutect2, varscan2
- FAM47C | c.1516C>G p.R506G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.864); catalogued as rs370557345, COSV63728974, COSV63729626; called by muse, mutect2, varscan2
- FAM71C | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV60943977; called by muse, mutect2, varscan2
- FAM81B | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV51985523; called by muse, mutect2, varscan2
- FAM83G | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV58760403; called by muse, mutect2, varscan2
- FAM9C | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61775817; called by muse, mutect2, varscan2
- FASTKD3 | c.891C>G p.S297R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV52945656; called by muse, mutect2, varscan2
- FBH1 | c.745G>A p.D249N (on ENST00000362091 / NM_178150.3; = p.D300N on NM_032807.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV62983765; called by muse, mutect2, varscan2
- FBN3 | c.6755-1G>C p.X2252_splice | Splice Site (SNP) | VAF 45/73 reads (62%) | catalogued as COSV54467513; called by muse, mutect2, varscan2
- FBXO28 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV64801070; called by muse, mutect2, varscan2
- FBXO43 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV71053726, COSV71054956; called by muse, mutect2, varscan2
- FEZF2 | c.1282A>G p.R428G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs76277372, COSV51863907; called by muse, mutect2, varscan2
- FGD6 | c.3748-1G>C p.X1250_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | catalogued as COSV59695440; called by muse, mutect2, varscan2
- FHL1 | c.491A>T p.K164M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV61782121; called by muse, mutect2, varscan2
- FLG2 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 38/418 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV66171139; called by muse, mutect2
- FLG2 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 140/194 reads (72%) | catalogued as COSV101165907; called by muse, mutect2, varscan2
- FLOT2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs1181266067, COSV101128941, COSV66684063; called by muse, mutect2, varscan2
- FLRT1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55364551; called by muse, mutect2, varscan2
- FOXC2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs1401459395, COSV57444272; called by muse, mutect2
- FOXD4L4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1205524971; called by mutect2, varscan2
- FOXJ2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs925597042, COSV50818109; called by muse, mutect2, varscan2
- FRAS1 | c.9736G>A p.E3246K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs977016304, COSV53630956; called by muse, mutect2, varscan2
- FREM1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV66527239; called by muse, mutect2, varscan2
- FSTL4 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779739; called by muse, mutect2, varscan2
- FUT3 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as rs560041767; called by muse, mutect2, varscan2
- FXR2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 112/124 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV51519900; called by muse, mutect2, varscan2
- FXYD5 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779297539, COSV61569465; called by muse, varscan2
- GAP43 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs771144272, COSV59346493; called by muse, mutect2, varscan2
- GARNL3 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59228874; called by muse, varscan2
- GBP7 | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV54010911; called by muse, mutect2, varscan2
- GDF3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61713261; called by muse, mutect2, varscan2
- GFRAL | c.1168A>T p.I390L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV61233460; called by muse, mutect2
- GGTLC1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1199163932, COSV99600717; called by muse, mutect2
- GIT1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV56611191; called by muse, mutect2, varscan2
- GKN1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65006261, COSV65006696; called by muse, mutect2, varscan2
- GLB1L3 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 99/119 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs1367566676, COSV68393179; called by muse, mutect2, varscan2
- GLT1D1 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV99896753; called by muse, mutect2
- GNA12 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.83); catalogued as COSV51743841; called by muse, mutect2, varscan2
- GOLGA4 | c.6392A>G p.E2131G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62712446; called by muse, mutect2, varscan2
- GPBP1 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV99302826; called by muse, mutect2, varscan2
- GPR19 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100196889; called by muse, mutect2, varscan2
- GRB2 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV57306172; called by muse, mutect2, varscan2
- GRIA1 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs13166146, COSV99600244; called by mutect2, varscan2
- GRIA4 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56910194; called by muse, mutect2, varscan2
- GRIA4 | c.2446G>A p.G816S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56910220; called by muse, mutect2, varscan2
- GRIK3 | c.2051A>T p.Y684F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66143762; called by muse, mutect2, varscan2
- GRIP1 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV54034521; called by muse, mutect2, varscan2
- GRM8 | c.2548C>G p.Q850E | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58850236; called by muse, mutect2, varscan2
- GSG1 | c.59C>T p.S20L (on ENST00000651961 / NM_001080555.4; = p.S7L on NM_031289.5) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs770721036, COSV60972556; called by muse, mutect2, varscan2
- GTF2A1 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | catalogued as COSV99993438; called by muse, mutect2, varscan2
- GTF2E2 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100577093, COSV63478141, COSV63478849; called by muse, mutect2, varscan2
- GTF3C3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV55833576; called by muse, mutect2, varscan2
- GUCY1A2 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.346); catalogued as rs769556757, COSV56491331, COSV56495250; called by muse, mutect2, varscan2
- H2BC12 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV63617436; called by muse, mutect2, varscan2
- H2BC5 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 63/427 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV56802707, COSV56803274; called by muse, mutect2, varscan2
- H2BC5 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV56802717, COSV56802846, COSV56804176; called by muse, mutect2
- HAS3 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54708394; called by muse, mutect2, varscan2
- HEATR5A | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66343744; called by muse, mutect2, varscan2
- HEATR6 | c.492C>G p.N164K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51745153, COSV99482365; called by muse, mutect2
- HECTD2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV99978605; called by muse, mutect2, varscan2
- HECW1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747487871, COSV67836190; called by muse, mutect2, varscan2
- HK2 | c.2321A>T p.E774V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51877764; called by muse, mutect2
- HLA-E | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64927732; called by muse, mutect2, varscan2
- HMCN1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437720763, COSV54923056; called by muse, mutect2, varscan2
- HOXA5 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1366664300, COSV56074276, COSV99762488; called by muse, mutect2, varscan2
- HSD11B1L | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV56799189; called by muse, mutect2, varscan2
- HSD3B2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV65593650, COSV65593700; called by muse, mutect2, varscan2
- HSP90B1 | c.2119G>C p.D707H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55356950; called by mutect2, varscan2
- HSPA13 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV53465942; called by muse, mutect2, varscan2
- HSPB3 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57357234; called by muse, mutect2, varscan2
- HTR1B | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100885408; called by muse, mutect2
- HTR2B | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV51450338; called by muse, mutect2, varscan2
- ICE1 | c.2613G>C p.Q871H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56829211; called by muse, mutect2, varscan2
- IFI16 | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV55536193, COSV99857642; called by muse, mutect2, varscan2
- IFT88 | c.180+2T>G p.X60_splice (on ENST00000319980 / NM_001318493.2; = p.X51_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV60675525; called by muse, mutect2, varscan2
- IGDCC3 | c.598C>G p.R200G | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV60077611, COSV60078909; called by muse, mutect2, varscan2
- IGHG2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764823624; called by muse, mutect2, varscan2
- IGSF9 | c.1322C>G p.S441C (on ENST00000368094 / NM_001135050.2; = p.S425C on NM_020789.4) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63641270; called by muse, mutect2
- IKZF2 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as COSV59581608; called by muse, mutect2, varscan2
- IL1RAPL1 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56283678; called by muse, mutect2, varscan2
- IMPDH2 | c.992G>C p.C331S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1261804434, COSV58708579; called by mutect2, varscan2
- IMPDH2 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1230857404, COSV58708585; called by muse, varscan2
- INHBA | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54221732; called by muse, mutect2, varscan2
- INPP5D | c.2449G>A p.E817K (on ENST00000445964 / NM_001017915.3; = p.E816K on NM_005541.5) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64038928; called by muse, varscan2
- IQGAP3 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV63250657; called by muse, mutect2, varscan2
- IRAG1 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.16); catalogued as COSV70212312; called by muse, varscan2
- IRAG2 | c.2872G>A p.D958N (on ENST00000636465; = p.D3N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV63137987; called by muse, mutect2, varscan2
- IRX1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57361291; called by muse, mutect2, varscan2
- ITGA4 | c.3070T>A p.Y1024N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59211239; called by muse, mutect2
- KANK4 | c.2926C>G p.H976D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV58093591; called by muse, mutect2, varscan2
- KANSL1 | c.2392+1G>A p.X798_splice | Splice Site (SNP) | VAF 48/78 reads (62%) | catalogued as COSV52271891; called by muse, mutect2, varscan2
- KAT14 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as COSV66608654; called by muse, mutect2, varscan2
- KAT7 | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1460051242, COSV52013387, COSV99371798; called by muse, mutect2
- KCNB2 | c.1158C>A p.D386E | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73051695; called by muse, mutect2
- KCNH8 | c.3212C>G p.S1071C | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV60464316, COSV60471238; called by muse, mutect2, varscan2
- KCNQ3 | c.2588C>A p.S863* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as rs1256140128, COSV101196177, COSV66478150; called by muse, mutect2, varscan2
- KDELR3 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV53249083; called by muse, mutect2, varscan2
- KDM6A | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV65043024; called by muse, mutect2, varscan2
- KEAP1 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV99407835; called by muse, mutect2
- KIAA0100 | c.4333C>A p.H1445N | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.3); catalogued as COSV66495232; called by muse, mutect2, varscan2
- KIAA0100 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV101197358, COSV66495243; called by muse, mutect2, varscan2
- KIAA0100 | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201619217, COSV66495251; called by muse, mutect2, varscan2
- KIAA0408 | c.1338C>A p.N446K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64107851; called by muse, mutect2, varscan2
- KIF1B | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV55813100, COSV55814891; called by muse, mutect2
- KIR3DL1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs369021301, COSV58492233; called by muse, varscan2
- KIT | c.2485-1G>A p.X829_splice | Splice Site (SNP) | VAF 21/237 reads (9%) | catalogued as CS022109, COSV55412816; called by muse, mutect2
- KLHL13 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53251012; called by muse, mutect2, varscan2
- KLHL17 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV58531871, COSV58532843; called by muse, mutect2, varscan2
- KLHL7 | c.854G>C p.R285T (on ENST00000339077 / NM_001031710.3; = p.R237T on NM_018846.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV59163287; called by muse, mutect2, varscan2
- KMT2D | c.15700G>T p.E5234* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs1159189200, COSV56459692, COSV56503806; called by muse, mutect2, varscan2
- KMT5B | c.1683G>C p.L561F | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV58566550; called by muse, mutect2, varscan2
- KNL1 | c.419C>G p.S140C (on ENST00000346991 / NM_170589.5; = p.S114C on NM_144508.5) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61158228; called by muse, mutect2, varscan2
- KRT17 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs756477246, COSV60861527; called by muse, mutect2, varscan2
- KRT24 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 122/200 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52881225; called by muse, mutect2, varscan2
- LACTB | c.833C>G p.S278* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99978956; called by muse, mutect2, varscan2
- LAMA1 | c.5413C>G p.L1805V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV67541068; called by muse, mutect2, varscan2
- LAMA3 | c.5707G>A p.E1903K (on ENST00000313654 / NM_198129.4; = p.E294K on NM_000227.6) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.279); catalogued as COSV52539514; called by muse, mutect2, varscan2
- LARS1 | c.1088C>G p.S363C (on ENST00000394434 / NM_020117.11; = p.S336C on NM_016460.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV50983024; called by muse, mutect2, varscan2
- LATS1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53586481, COSV53590554; called by muse, mutect2, varscan2
- LBP | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV54142097; called by muse, mutect2, varscan2
- LCMT2 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2, varscan2
- LCOR | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs543729847, COSV53717485; called by muse, mutect2, varscan2
- LETMD1 | c.384G>C p.L128F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50398703; called by muse, mutect2, varscan2
- LGR6 | c.970C>T p.L324F (on ENST00000367278 / NM_001017403.1; = p.L272F on NM_021636.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55162518; called by muse, mutect2, varscan2
- LHX2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); catalogued as rs775730128, COSV65317722, COSV65317948; called by muse, mutect2, varscan2
- LIAS | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.41); catalogued as rs796052701, COSV54696560; ClinVar: uncertain significance; called by muse, varscan2
- LIAS | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54696569; called by muse, varscan2
- LIF | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.292); catalogued as rs759058256, COSV50777009; called by muse, mutect2, varscan2
- LIG1 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54394175; called by muse, mutect2, varscan2
- LMOD2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV71755611; called by muse, mutect2, varscan2
- LMTK2 | c.4466C>T p.S1489L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383830900, COSV52000499; called by muse, mutect2, varscan2
- LMTK3 | c.4240G>C p.E1414Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1198502196, COSV54315451; called by muse, mutect2, varscan2
- LPCAT3 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as COSV54646778; called by muse, varscan2
- LRCH3 | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481276099, COSV58394894; called by muse, mutect2, varscan2
- LRP12 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs773155721, COSV52632081; called by muse, mutect2, varscan2
- LRP2 | c.6891G>T p.L2297F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143893803, COSV99790677; called by muse, mutect2, varscan2
- LRRC37B | c.1896-1G>T p.X632_splice | Splice Site (SNP) | VAF 43/87 reads (49%) | catalogued as COSV58953813; called by muse, mutect2, varscan2
- LRRC43 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100336723, COSV60291766; called by muse, mutect2, varscan2
- LRRC66 | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV58634176, COSV58635621; called by muse, mutect2
- LRRIQ1 | c.3620T>C p.L1207P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67835352; called by muse, mutect2, varscan2
- LRRIQ3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 56/124 reads (45%) | catalogued as rs772962612, COSV100599578, COSV63041706; called by muse, mutect2, varscan2
- LRRK2 | c.3892C>T p.P1298S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs865865671, COSV54162911; called by muse, mutect2, varscan2
- LRRK2 | c.5140G>C p.E1714Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); catalogued as COSV54162928; called by muse, mutect2, varscan2
- LTBP4 | c.4093C>G p.R1365G (on ENST00000308370 / NM_001042544.1; = p.R1328G on NM_003573.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as rs770949379, COSV99193450; called by muse, varscan2
- LY6G5B | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as rs142186859; called by muse, mutect2
- LYST | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371185792; called by muse, mutect2, varscan2
- MAEA | c.737C>G p.P246R (on ENST00000303400 / NM_001017405.3; = p.P205R on NM_005882.5) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99295496; called by muse, mutect2
- MAGI3 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100289284, COSV56841188; called by muse, mutect2, varscan2
- MAP10 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101406510; called by mutect2, varscan2
- MAP3K12 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57234717; called by muse, mutect2, varscan2
- MAP3K15 | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761341022, COSV58834983; called by muse, varscan2
- MAP3K5 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 76/114 reads (67%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.795); catalogued as rs1466653227, COSV62888496, COSV62890832; called by muse, mutect2, varscan2
- MAP3K9 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.276); catalogued as rs1485126606, COSV67122298; called by muse, mutect2, varscan2
- MAP4K3 | c.1602T>G p.N534K | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55716098; called by muse, mutect2, varscan2
- MAPRE1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV65032962, COSV65033299, COSV65033623; called by muse, mutect2, varscan2
- MATN1 | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65651131; called by muse, mutect2, varscan2
- MBD3 | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV50084796; called by muse, mutect2, varscan2
- MC1R | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV59626302; called by muse, mutect2, varscan2
- MCTP2 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV59147378; called by muse, mutect2, varscan2
- MECOM | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV72110655, COSV72110930; called by muse, mutect2, varscan2
- MED1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.498); catalogued as COSV56127261, COSV56127700; called by muse, mutect2, varscan2
- MED14 | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1165393504, COSV61357585, COSV61357804; called by muse, mutect2, varscan2
- MET | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV59261748; called by muse, mutect2, varscan2
- METTL25 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99942369; called by muse, mutect2
- MEX3C | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV68530258; called by muse, mutect2, varscan2
- MFSD5 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.362); catalogued as COSV61565914; called by muse, mutect2, varscan2
- MFSD9 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 39/57 reads (68%) | catalogued as COSV51492729, COSV99302119, COSV99302265; called by muse, mutect2, varscan2
- MGA | c.2605G>C p.D869H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as COSV54950452, COSV54957942, COSV54959479; called by muse, mutect2, varscan2
- MGAM | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101516442; called by muse, mutect2, varscan2
- MICU3 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58846325, COSV58847595; called by muse, mutect2, varscan2
- MIER3 | c.1426G>C p.E476Q (on ENST00000381199 / NM_001297599.2; = p.E475Q on NM_152622.4) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV67083168; called by muse, mutect2, varscan2
- MIER3 | c.1249G>C p.D417H (on ENST00000381199 / NM_001297599.2; = p.D416H on NM_152622.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as COSV67083171; called by muse, mutect2, varscan2
- MIER3 | c.1013G>C p.R338T (on ENST00000381199 / NM_001297599.2; = p.R337T on NM_152622.4) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV101167565, COSV67083178; called by muse, varscan2
- MINDY4 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as rs770851252, COSV99518726; called by muse, mutect2, varscan2
- MIS18BP1 | c.165G>C p.L55F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60372329, COSV60372398; called by muse, mutect2, varscan2
- MKI67 | c.7717G>A p.E2573K | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0.15); catalogued as COSV64075718; called by muse, mutect2, varscan2
- MKI67 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs1158499483, COSV64077569; called by muse, mutect2, varscan2
- MKLN1 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100759847; called by muse, mutect2, varscan2
- MPP5 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746157195, COSV55531307; called by muse, mutect2, varscan2
- MRGPRX1 | c.858C>G p.N286K | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV57108791; called by muse, mutect2, varscan2
- MROH2B | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101270697, COSV68180982; called by muse, mutect2, varscan2
- MROH9 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV63012535; called by muse, mutect2, varscan2
- MROH9 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as COSV63012540; called by muse, mutect2, varscan2
- MTHFD2 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as COSV51201163, COSV51201972; called by muse, mutect2, varscan2
- MTHFR | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV64878501; called by muse, mutect2, varscan2
- MTIF3 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV63528667; called by muse, mutect2, varscan2
- MTMR10 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58729186; called by muse, mutect2, varscan2
- MTMR4 | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV60202026; called by muse, mutect2, varscan2
- MTMR9 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs764644468, COSV55314304, COSV99644180; called by muse, mutect2, varscan2
- MXRA5 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV54243671; called by muse, mutect2, varscan2
- MYH7B | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1275356540, COSV53423200; called by muse, mutect2, varscan2
- MYO16 | c.3099G>T p.K1033N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV62756933; called by muse, mutect2, varscan2
- MYO5A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62556726; called by muse, mutect2, varscan2
- MYT1L | c.3511C>G p.L1171V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101217158, COSV67703912; called by muse, varscan2
- NASP | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63114033; called by muse, mutect2, varscan2
- NAV3 | c.2195A>G p.N732S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765945791, COSV57099750; called by muse, varscan2
- NBN | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs772411713, COSV55375303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBR1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57834365; called by muse, mutect2, varscan2
- NDUFA9 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs778957183, COSV56928863, COSV56930784; called by muse, mutect2, varscan2
- NDUFS2 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV63488306; called by muse, mutect2, varscan2
- NDUFV2 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV50821964; called by muse, varscan2
- NEBL | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV65799971; called by muse, mutect2, varscan2
- NEDD4 | c.1834C>G p.L612V (on ENST00000508342 / NM_001284338.1; = p.L193V on NM_006154.4) | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV59062768; called by muse, mutect2, varscan2
- NEIL2 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52707447; called by muse, mutect2, varscan2
- NEO1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56073972, COSV56075672; called by muse, mutect2, varscan2
- NEO1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV56075682; called by muse, mutect2, varscan2
- NF1 | c.6356G>C p.R2119T (on ENST00000358273 / NM_001042492.3; = p.R2098T on NM_000267.3) | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62212688; called by muse, mutect2, varscan2
- NF1 | c.6577G>A p.E2193K (on ENST00000358273 / NM_001042492.3; = p.E2172K on NM_000267.3) | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as BM1390660, COSV62212697; called by muse, mutect2, varscan2
- NF1 | c.6705-1G>T p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 61/112 reads (54%) | catalogued as CS000886, COSV62198415; called by muse, mutect2, varscan2
- NFASC | c.928G>C p.D310H (on ENST00000339876 / NM_001378329.1; = p.D321H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58373489; called by muse, mutect2, varscan2
- NFAT5 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV63030411; called by muse, mutect2, varscan2
- NHS | c.3602C>G p.T1201S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV66279307; called by muse, mutect2, varscan2
- NIM1K | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV58144068; called by muse, mutect2, varscan2
- NKAP | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139829965, COSV57630772; called by muse, mutect2, varscan2
- NKAPL | c.1149G>C p.K383N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV59197112, COSV59198701; called by muse, mutect2, varscan2
- NLRP5 | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101173709; called by muse, mutect2
- NLRP8 | c.2098G>C p.A700P | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.424); catalogued as COSV52591333; called by muse, mutect2, varscan2
- NOL11 | c.1298T>C p.I433T | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs547196290, COSV53524679; called by muse, mutect2, varscan2
- NOTCH1 | c.6995C>T p.P2332L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV53074745; called by muse, mutect2, varscan2
- NOTCH1 | c.6050C>G p.S2017* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as CD159420, COSV53042787; called by muse, mutect2, varscan2
- NOTCH1 | c.5816C>G p.S1939* | Nonsense Mutation (SNP) | VAF 42/136 reads (31%) | catalogued as COSV99488462; called by muse, mutect2, varscan2
- NPC1L1 | c.1188C>A p.F396L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV56928305; called by muse, mutect2, varscan2
- NPHP3 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV58632085; called by muse, mutect2, varscan2
- NRCAM | c.1354G>A p.E452K (on ENST00000379028 / NM_001371124.1; = p.E446K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV61043999; called by muse, mutect2, varscan2
- NUDT5 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 27/208 reads (13%) | catalogued as COSV58502538; called by muse, mutect2, varscan2
- NUP205 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781255463, COSV53654794, COSV53663443; called by muse, mutect2, varscan2
- NUP210L | c.4145G>C p.R1382P | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55153541; called by muse, mutect2, varscan2
- OBSCN | c.11419G>T p.D3807Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV52805022; called by muse, mutect2, varscan2
- OFD1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV60793962, COSV60797667; called by muse, mutect2, varscan2
- OR10H4 | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV59062473; called by muse, mutect2
- OR11H12 | c.647C>A p.T216N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV101612498; called by mutect2, varscan2
- OR2AK2 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.62); PolyPhen benign (0.3); catalogued as COSV63557766; called by muse, mutect2, varscan2
- OR2B2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755935657, COSV57579777, COSV57580340; called by muse, mutect2
- OR4C6 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58602943; called by muse, mutect2, varscan2
- OR4N2 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100270086, COSV60052363, COSV60053507; called by muse, mutect2, varscan2
- OR51S1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV59059372; called by muse, mutect2
- OR52A5 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56614536, COSV56616097; called by muse, mutect2, varscan2
- OR5AS1 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs773462317, COSV57982651, COSV57982974; called by muse, mutect2, varscan2
- OR5H14 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV71194319; called by muse, mutect2, varscan2
- OR5H2 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1370081847; called by muse, mutect2, varscan2
- OR5W2 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV60617515; called by muse, mutect2, varscan2
- OR8H2 | c.635T>C p.F212S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57946592; called by muse, mutect2, varscan2
- OSBP | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758673285, COSV55660772, COSV55664563; called by muse, mutect2, varscan2
- OTUD4 | c.3256C>G p.Q1086E (on ENST00000447906 / NM_001366057.1; = p.Q1021E on NM_001102653.1) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs748391198, COSV101485994; called by muse, mutect2, varscan2
- PACSIN2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54321676; called by muse, mutect2, varscan2
- PAGR1 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV56190604, COSV56191004; called by muse, mutect2, varscan2
- PAQR8 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as COSV62443258; called by muse, mutect2, varscan2
- PARD3 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV61063993; called by muse, mutect2, varscan2
- PARP14 | c.3879G>C p.L1293F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71735253; called by muse, mutect2
- PASD1 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64855475, COSV64856634; called by muse, mutect2, varscan2
- PAX2 | c.940G>C p.E314Q (on ENST00000428433 / NM_003987.5; = p.E291Q on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.555); catalogued as COSV62292265; called by muse, mutect2, varscan2
- PCCA | c.1545C>G p.H515Q | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0.269); catalogued as COSV66196060; called by muse, mutect2, varscan2
- PCDH10 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52088545; called by muse, mutect2, varscan2
- PCDHA11 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV56496095; called by muse, mutect2, varscan2
- PCDHA9 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); catalogued as COSV65329986; called by muse, mutect2, varscan2
- PCDHB8 | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV50796452; called by muse, mutect2, varscan2
- PCLO | c.6463G>T p.E2155* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100436363, COSV61638480; called by muse, mutect2, varscan2
- PCLO | c.4393G>C p.E1465Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as COSV61653165; called by muse, mutect2, varscan2
- PCMTD1 | c.1053G>C p.L351F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62124244; called by muse, mutect2, varscan2
- PCNA | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs747916514, COSV52532897; called by muse, mutect2, varscan2
- PCSK5 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs778522255, COSV65093331; called by muse, mutect2, varscan2
- PCSK7 | c.1285C>A p.R429S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58007132, COSV58008714; called by muse, mutect2
- PDE4B | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV58475613; called by muse, mutect2, varscan2
- PDE4DIP | c.5961-1G>A p.X1987_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV57701808, COSV57716815; called by mutect2, varscan2
- PDYN | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV54102792; called by muse, mutect2, varscan2
- PEG3 | c.3592G>T p.D1198Y | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as COSV55641595, COSV99689735; called by muse, mutect2, varscan2
- PER3 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62707082; called by muse, mutect2, varscan2
- PEX14 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV63062533; called by muse, mutect2, varscan2
- PHF20 | c.1869G>C p.W623C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59184789, COSV59187703; called by muse, mutect2, varscan2
- PHLDB2 | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV67314329; called by muse, mutect2, varscan2
- PI4KA | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55417914; called by muse, mutect2, varscan2
- PIDD1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs779465093, COSV61705492, COSV61706380; called by muse, mutect2, varscan2
- PIK3C2A | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56405191; called by muse, mutect2, varscan2
- PIK3C2G | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.124); catalogued as rs746276290, COSV56822264; called by muse, mutect2, varscan2
- PILRB | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.144); catalogued as rs189717427; called by muse, mutect2, varscan2
- PIP5K1C | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs368186552; called by muse, mutect2, varscan2
- PJA1 | c.1301G>C p.G434A (on ENST00000361478 / NM_145119.4; = p.G246A on NM_022368.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.149); catalogued as COSV64053553; called by muse, mutect2, varscan2
- PLCB4 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53811194; called by muse, mutect2, varscan2
- PLCD3 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV59561969; called by muse, mutect2, varscan2
- PLCL2 | c.1321C>G p.H441D (on ENST00000615277 / NM_001144382.2; = p.H315D on NM_015184.5) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67622272, COSV67623934; called by muse, mutect2, varscan2
- PLD1 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs540439098, COSV60568108; called by muse, mutect2, varscan2
- PLEKHA2 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV66243194; called by muse, mutect2, varscan2
- PLEKHA4 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54364864; called by muse, mutect2, varscan2
- PLK2 | c.860A>G p.E287G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57109002; called by muse, mutect2, varscan2
- PLTP | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV51943854; called by muse, mutect2, varscan2
- PLXND1 | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as rs771247738, COSV60716964; called by muse, mutect2, varscan2
- PNISR | c.1175G>C p.G392A | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1412730882, COSV65080196; called by muse, mutect2, varscan2
- PNLDC1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51706948; called by muse, mutect2, varscan2
- PNPLA3 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV53379752; called by muse, mutect2, varscan2
- POGZ | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 99/142 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV55039626; called by muse, mutect2, varscan2
- POLG | c.1322G>C p.W441S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51523480; called by muse, mutect2
- POLK | c.2234C>G p.S745C | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54037757, COSV99605706; called by muse, mutect2, varscan2
- POU6F1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV61327413; called by muse, mutect2, varscan2
- PPFIA2 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100333674; called by muse, mutect2
- PPP1R10 | c.2462G>C p.G821A | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as COSV64739986; called by muse, mutect2, varscan2
- PPP1R35 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV52769636; called by muse, mutect2, varscan2
- PPP2R3A | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV53868068; called by muse, mutect2, varscan2
- PPP4R1 | c.2811A>C p.K937N (on ENST00000400556 / NM_001042388.3; = p.K920N on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV53283441; called by muse, mutect2, varscan2
- PPP4R3B | c.1999G>A p.E667K (on ENST00000616407 / NM_001122964.3; = p.E582K on NM_020463.4) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs1306457599, COSV55407535; called by muse, mutect2, varscan2
- PPP4R3B | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV55404443; called by muse, mutect2, varscan2
- PPP4R3B | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV55407568; called by muse, mutect2, varscan2
- PPP4R3B | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55407586; called by muse, mutect2, varscan2
- PPP6C | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65208612; called by muse, mutect2, varscan2
- PRKCSH | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.332); catalogued as rs1259633067, COSV52952863; called by muse, mutect2, varscan2
- PRKDC | c.8689C>G p.L2897V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV58059286; called by muse, mutect2, varscan2
- PRPSAP1 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV61212128; called by muse, varscan2
- PRRC1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV56990724, COSV99687935; called by muse, mutect2, varscan2
- PRUNE2 | c.6019G>T p.E2007* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100944653; called by muse, mutect2, varscan2
- PRUNE2 | c.4058C>A p.S1353* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100944655; called by muse, mutect2, varscan2
- PSMD3 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV52857172, COSV52858957; called by muse, mutect2, varscan2
- PTBP2 | c.1312G>C p.D438H (on ENST00000426398 / NM_001300986.2; = p.D430H on NM_021190.4) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64624145, COSV64625771; called by muse, mutect2, varscan2
- PTCD1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs534734137, COSV52858613; called by muse, mutect2, varscan2
- PTDSS1 | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV61265770; called by muse, mutect2, varscan2
- PTHLH | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as rs1473898006, COSV52368815; called by muse, mutect2, varscan2
- PTHLH | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV52368837; called by muse, mutect2, varscan2
- PTPN4 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV55305982; called by muse, mutect2, varscan2
- PTPRF | c.5371C>G p.Q1791E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV63447181; called by muse, mutect2
- PTPRN2 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66104992; called by muse, mutect2
- PTPRS | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.743); catalogued as rs1488356054, COSV99510830; called by muse, mutect2
- PUM2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.306); catalogued as COSV57583553; called by muse, mutect2, varscan2
- QSER1 | c.3791-1G>C p.X1264_splice (on ENST00000399302; = p.X1393_splice on NM_001076786.3) | Splice Site (SNP) | VAF 14/114 reads (12%) | catalogued as COSV67901280; called by muse, mutect2, varscan2
- QSER1 | c.5107G>C p.E1703Q (on ENST00000399302; = p.E1832Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV67901283; called by muse, mutect2, varscan2
- RABEP2 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs202177661, COSV62870351, COSV62871233; called by muse, mutect2, varscan2
- RABL2A | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV64573336; called by muse, mutect2, varscan2
- RAI1 | c.1466C>G p.S489* | Nonsense Mutation (SNP) | VAF 12/16 reads (75%) | catalogued as COSV55392821; called by muse, mutect2, varscan2
- RALYL | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1324539685, COSV101569249; called by muse, mutect2
- RANBP2 | c.5495C>T p.S1832F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51705488; called by muse, mutect2, varscan2
- RAPGEF2 | c.1590G>C p.R530S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs149086317, COSV52431660; called by muse, mutect2, varscan2
- RASAL1 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55658280; called by muse, mutect2, varscan2
- RASGRP3 | c.660A>T p.E220D | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV67823831; called by muse, mutect2, varscan2
- RASSF8 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV51454676; called by muse, mutect2, varscan2
- RB1CC1 | c.3643G>C p.D1215H | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV50261511; called by muse, mutect2, varscan2
- RBM17 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV65914541; called by muse, mutect2, varscan2
- RBM23 | c.466G>C p.D156H (on ENST00000359890 / NM_001077351.2; = p.D140H on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV57128450; called by muse, mutect2, varscan2
- RBMXL1 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53103917; called by muse, mutect2, varscan2
- RC3H1 | c.2794C>G p.Q932E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV51207711; called by muse, mutect2, varscan2
- RELN | c.4214G>C p.G1405A | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59022277; called by muse, mutect2, varscan2
- REPS1 | c.2191C>G p.L731V (on ENST00000450536 / NM_001286611.2; = p.L730V on NM_031922.4) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as COSV57812712, COSV99238609; called by muse, mutect2, varscan2
- REV3L | c.4888G>C p.E1630Q | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV62621593; called by muse, mutect2, varscan2
- RFTN1 | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 32/231 reads (14%) | catalogued as COSV100489410; called by muse, mutect2, varscan2
- RFTN2 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99695649; called by muse, mutect2, varscan2
- RGL4 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99318761; called by muse, mutect2, varscan2
- RGMA | c.1092C>A p.C364* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as rs902429017, COSV100224409; called by muse, mutect2, varscan2
- RHBG | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV54805679, COSV54807935; called by muse, mutect2, varscan2
- RIC1 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as rs148688426; called by muse, mutect2, varscan2
- RIMS2 | c.4162G>C p.E1388Q (on ENST00000666250 / NM_001348490.2; = p.E959Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51704801; called by muse, mutect2, varscan2
- RLF | c.4130A>C p.K1377T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65652608; called by muse, mutect2, varscan2
- RMND1 | c.1136G>C p.R379T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60551339; called by muse, mutect2, varscan2
- RNF40 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV61215915; called by muse, mutect2, varscan2
- ROR2 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs779047326, COSV65221964, COSV65221975; called by muse, mutect2, varscan2
- RORB | c.69T>G p.I23M (on ENST00000396204 / NM_001365023.1; = p.I12M on NM_006914.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65338444; called by muse, mutect2, varscan2
- RP1L1 | c.5968G>C p.E1990Q | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.734); catalogued as COSV66758181; called by muse, mutect2, varscan2
- RPGRIP1L | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV50911979; called by muse, mutect2, varscan2
- RSPH4A | c.2089C>G p.L697V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57635980; called by muse, mutect2, varscan2
- RSU1 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100590346, COSV61713658; called by muse, mutect2, varscan2
- RTEL1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV58898384; called by muse, mutect2, varscan2
- RTN3 | c.1612G>C p.E538Q (on ENST00000377819 / NM_001265589.2; = p.E519Q on NM_201428.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV58029634, COSV58030584; called by muse, mutect2, varscan2
- RTP2 | c.181T>G p.C61G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64079272; called by muse, mutect2, varscan2
- RUNX1T1 | c.674C>T p.S225L (on ENST00000265814 / NM_001198628.1; = p.S198L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV56156450; called by muse, mutect2, varscan2
- RYR2 | c.13010C>G p.P4337R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773113, COSV63680248, COSV63701662; called by muse, mutect2, varscan2
- SAMD4B | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 118/185 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs763484728, COSV58752631; called by muse, mutect2, varscan2
- SAMD9L | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as rs537725298, COSV100560768, COSV59082822; called by muse, mutect2, varscan2
- SBNO1 | c.3748C>G p.L1250V (on ENST00000420886; = p.L1249V on NM_018183.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs941360439, COSV57344145; called by muse, mutect2, varscan2
- SCAF4 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV54590275; called by muse, mutect2, varscan2
- SCG2 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV59539380; called by muse, mutect2, varscan2
- SCN11A | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV56574602; called by muse, mutect2
- SDR16C5 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.497); catalogued as rs1320158879, COSV58127555; called by muse, mutect2, varscan2
- SDSL | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs548878499, COSV61885040; called by muse, mutect2, varscan2
- SEC23IP | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64832415; called by muse, mutect2, varscan2
- SEC61A2 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV53653913; called by muse, mutect2, varscan2
- SEMA3B | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100312763, COSV100312815; called by muse, mutect2, varscan2
- SEZ6L2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58101799; called by muse, mutect2, varscan2
- SF3B2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV59429359; called by muse, mutect2, varscan2
- SFMBT1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs748760209, COSV56251608; called by muse, mutect2, varscan2
- SGMS1 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV62371669; called by muse, mutect2, varscan2
- SH3YL1 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62157193; called by muse, varscan2
- SHANK1 | c.6233C>T p.P2078L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1347899350, COSV53247342, COSV53257369; called by muse, mutect2, varscan2
- SHMT2 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100197202; called by muse, mutect2
- SHROOM4 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56789594, COSV56794468; called by muse, mutect2, varscan2
- SIRT1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53019479; called by muse, mutect2, varscan2
- SLAIN1 | c.1115C>T p.S372L (on ENST00000466548; = p.S109L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.051); catalogued as COSV57388089; called by muse, mutect2, varscan2
- SLAMF7 | c.765A>T p.Q255H | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as COSV63563773; called by muse, mutect2, varscan2
- SLC12A7 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1166949429, COSV53756215; called by muse, mutect2, varscan2
- SLC22A10 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100235784; called by muse, mutect2
- SLC24A3 | c.1119C>G p.I373M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1266085479, COSV60126759; called by muse, mutect2, varscan2
- SLC26A8 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV62886954; called by muse, mutect2, varscan2
- SLC27A3 | c.785C>T p.A262V (on ENST00000271857; = p.A134V on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV55162194; called by muse, mutect2
- SLC38A3 | c.375C>T p.G125= | Splice Region (SNP) | VAF 20/32 reads (63%) | catalogued as COSV101309938; called by muse, mutect2, varscan2
- SLC39A1 | c.742T>A p.C248S | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57844798; called by muse, mutect2, varscan2
- SLC39A12 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1407620191, COSV66201017; called by muse, mutect2, varscan2
- SLC4A5 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV61030803; called by muse, mutect2, varscan2
- SLC5A11 | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61742876; called by muse, mutect2, varscan2
- SLC5A12 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV54823520; called by muse, mutect2, varscan2
- SLC6A16 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV60029184, COSV60029227; called by muse, mutect2, varscan2
- SLC9A3R2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs763419418, COSV54593700; called by muse, mutect2, varscan2
- SLIT2 | c.1904T>A p.L635H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56562227; called by muse, mutect2, varscan2
- SLX4IP | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1479295904, COSV57949319; called by muse, mutect2, varscan2
- SMURF2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1555687847, COSV52317887; called by muse, mutect2
- SNX33 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185683285, COSV57914096; called by muse, mutect2, varscan2
- SOS1 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67676700; called by muse, mutect2, varscan2
- SOWAHB | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV57554876, COSV57554932; called by muse, mutect2, varscan2
- SOX5 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58640187; called by muse, mutect2, varscan2
- SP140 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV59452894; called by muse, mutect2, varscan2
- SPATA31A1 | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1468217021; called by muse, mutect2, varscan2
- SPATA32 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV59303637, COSV59304497; called by muse, mutect2, varscan2
- SPRN | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV58154655; called by muse, mutect2
- SPTA1 | c.3411C>G p.I1137M | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.349); catalogued as COSV63757090; called by muse, mutect2, varscan2
- SPTAN1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV63988852; called by muse, mutect2, varscan2
- SPTLC3 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100983153; called by muse, mutect2, varscan2
- SRCAP | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as rs758980895, COSV52677566, COSV99349196; called by muse, mutect2, varscan2
- SRPK2 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV57577174; called by muse, mutect2, varscan2
- SRRM2 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57072793, COSV57075432; called by muse, mutect2, varscan2
- SRRM2 | c.3775G>C p.E1259Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs779842483, COSV57077854; called by muse, mutect2
- SRRM2 | c.4424G>C p.R1475T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as rs777496308, COSV57077864; called by muse, mutect2, varscan2
- ST3GAL6 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54583495, COSV99504752; called by muse, mutect2, varscan2
- STAB2 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.194); catalogued as COSV101186467, COSV66343565; called by muse, mutect2, varscan2
- STAG3 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs763706357, COSV57933267; called by muse, mutect2, varscan2
- STARD3NL | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.741); catalogued as COSV50519227; called by muse, mutect2, varscan2
- STK19 | c.833G>C p.G278A (on ENST00000375333 / NM_032454.1; = p.G274A on NM_004197.1) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64692657; called by muse, mutect2, varscan2
- STX2 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV55433244; called by muse, mutect2, varscan2
- STXBP5 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1395049129, COSV51655676; called by muse, mutect2, varscan2
- STXBP5L | c.2483C>G p.S828C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV56525669; called by muse, mutect2, varscan2
- SUPT16H | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99359906; called by muse, mutect2
- SVIL | c.6505G>C p.E2169Q (on ENST00000355867 / NM_021738.3; = p.E1743Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV63446034; called by muse, mutect2, varscan2
- SVIL | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV63446040; called by muse, mutect2, varscan2
- SYN2 | c.1716G>C p.L572F | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70285963; called by muse, mutect2
- SYNE2 | c.18324G>C p.Q6108H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100647788, COSV59952244; called by muse, mutect2
- TAB1 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1313656416, COSV53372440; called by muse, mutect2, varscan2
- TAB1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53372445; called by muse, mutect2, varscan2
- TAB1 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304643841, COSV53372454; called by muse, mutect2, varscan2
- TACC3 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs765878922, COSV57606661; called by muse, mutect2, varscan2
- TAF1 | c.5032G>C p.D1678H (on ENST00000373790 / NM_138923.4; = p.D1699H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV52120508; called by muse, mutect2, varscan2
- TALDO1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs1391258906, COSV100032914, COSV59798145; called by muse, mutect2, varscan2
- TAP1 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs765013700, COSV62753796, COSV62755273; called by muse, mutect2, varscan2
- TAS2R30 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs200441706, COSV67860478; called by muse, mutect2, varscan2
- TAX1BP1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55296659; called by muse, mutect2
- TBC1D16 | c.689C>A p.S230* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100188086; called by muse, mutect2
- TBC1D16 | c.530C>G p.S177W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs201402527, COSV100188088; called by muse, varscan2
- TBC1D2 | c.2511G>C p.L837F (on ENST00000465784 / NM_001267571.2; = p.L826F on NM_018421.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59787163; called by muse, mutect2, varscan2
- TBC1D31 | c.2111G>C p.R704T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV54869053; called by muse, mutect2, varscan2
- TCFL5 | c.1209G>C p.E403D | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53897593; called by muse, mutect2
- TCHP | c.1406C>G p.S469* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV57165445; called by muse, mutect2, varscan2
- TCP1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58459898; called by muse, mutect2, varscan2
- TEC | c.1205A>T p.E402V | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV67405720; called by muse, mutect2, varscan2
- TENM2 | c.1484T>G p.I495R (on ENST00000518659 / NM_001122679.2; = p.I263R on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV69137044; called by muse, mutect2, varscan2
- TENM3 | c.4672G>T p.D1558Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV69314658; called by muse, mutect2, varscan2
- TEP1 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as COSV52996727; called by muse, mutect2, varscan2
- TET1 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV65387401; called by muse, varscan2
- TET1 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65384983, COSV65387406; called by muse, mutect2, varscan2
- TFG | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99426986; called by muse, mutect2, varscan2
- TG | c.6241C>A p.L2081M | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs114087638, COSV55087680; called by muse, mutect2, varscan2
- TGDS | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54301898; called by muse, mutect2, varscan2
- TGIF1 | c.646C>T p.P216S (on ENST00000330513 / NM_001374396.1; = p.P236S on NM_003244.4) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57906671; called by muse, mutect2, varscan2
- THRAP3 | c.2357C>T p.S786L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV63569054; called by muse, varscan2
- THRAP3 | c.2435C>G p.S812* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100663410; called by muse, varscan2
- TIAM1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV54553422; called by muse, mutect2, varscan2
- TICRR | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544669; called by muse, mutect2, varscan2
- TLK2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.071); catalogued as COSV100409249; called by muse, varscan2
- TLK2 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.129); catalogued as COSV100409254; called by muse, varscan2
- TMEM184C | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV56854335; called by muse, mutect2, varscan2
- TMEM65 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52631390; called by muse, mutect2, varscan2
- TMEM87B | c.1659G>C p.K553N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV51715078, COSV51717004; called by muse, mutect2, varscan2
- TNKS2 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as COSV65416234; called by muse, mutect2, varscan2
- TOMM20 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64014159; called by muse, mutect2, varscan2
- TPO | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61111549; called by muse, mutect2
- TRIM2 | c.305C>A p.S102Y (on ENST00000437508; = p.S129Y on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV58636842; called by muse, mutect2, varscan2
- TRIM2 | c.491C>T p.S164L (on ENST00000437508; = p.S191L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs139035351; called by muse, mutect2, varscan2
- TRIM21 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV54345411; called by muse, mutect2, varscan2
- TRIM24 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58975769; called by muse, mutect2, varscan2
- TRIM39 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.678); catalogued as COSV100935918, COSV64955688; called by muse, mutect2, varscan2
- TRIM42 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1250313209, COSV53883465; called by muse, mutect2, varscan2
- TRPM6 | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as rs753358405, COSV100666426; called by muse, mutect2, varscan2
- TRPM7 | c.5003T>C p.L1668P | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57919652; called by muse, mutect2, varscan2
- TRPM8 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100224236, COSV61223157, COSV61223252; called by muse, mutect2, varscan2
- TRPV5 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54688054; called by muse, mutect2, varscan2
- TRRAP | c.4082C>G p.S1361* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as COSV100722533, COSV62856378; called by muse, mutect2, varscan2
- TSPAN3 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs185158565, COSV51215509; called by muse, mutect2, varscan2
- TSPAN31 | c.445-1G>C p.X149_splice | Splice Site (SNP) | VAF 21/41 reads (51%) | catalogued as COSV57276725; called by muse, mutect2, varscan2
- TSR1 | c.2266G>C p.D756H | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56786228, COSV56786287; called by muse, mutect2, varscan2
- TTC13 | c.367-1G>C p.X123_splice | Splice Site (SNP) | VAF 14/25 reads (56%) | catalogued as COSV64169289; called by mutect2, varscan2
- TTN | c.96599C>T p.S32200L (on ENST00000591111; = p.S24776L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | PolyPhen possibly damaging (0.54); catalogued as COSV60222691; called by muse, mutect2, varscan2
- TTN | c.93976G>C p.E31326Q (on ENST00000591111; = p.E23902Q on NM_003319.4) | Missense Mutation (SNP) | VAF 30/44 reads (68%) | PolyPhen probably damaging (0.997); catalogued as rs540132942, COSV60222733, COSV60387361; called by muse, mutect2, varscan2
- TTN | c.2116G>A p.V706I (on ENST00000591111; = p.V660I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/28 reads (64%) | PolyPhen possibly damaging (0.488); catalogued as rs755751370, COSV60222773; called by muse, mutect2, varscan2
- TTN | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | PolyPhen probably damaging (0.997); catalogued as COSV60222826; called by muse, mutect2, varscan2
- TUB | c.64T>C p.F22L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV59492031; called by muse, mutect2, varscan2
- TUBB4B | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs747212339, COSV61118257; called by muse, mutect2, varscan2
- TUT7 | c.3379G>T p.A1127S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52897499; called by muse, mutect2, varscan2
- TXNIP | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65220977; called by muse, mutect2
- TYW3 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs1011959814, COSV61718306; called by muse, mutect2, varscan2
- UBR4 | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.954); catalogued as COSV64395230; called by muse, mutect2, varscan2
- UBXN4 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1371175056, COSV55636610; called by muse, mutect2, varscan2
- UGT2B28 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100158834; called by muse, mutect2, varscan2
- UROC1 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV52033938, COSV52036703; called by muse, mutect2, varscan2
- USP17L2 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61556210; called by muse, mutect2, varscan2
- USP26 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV63709318; called by muse, mutect2, varscan2
- USP37 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51441870, COSV51445517; called by muse, mutect2, varscan2
- USP7 | c.1506T>G p.D502E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV61216280; called by muse, mutect2, varscan2
- VAV1 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58378882, COSV58388246; called by muse, mutect2, varscan2
- VAV1 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408687, COSV58388263; called by muse, mutect2, varscan2
- VEZT | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763560318, COSV54142629; called by muse, mutect2, varscan2
- VMP1 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.465); catalogued as COSV51870410; called by muse, mutect2, varscan2
- VPS16 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV66797215; called by muse, mutect2, varscan2
- VPS8 | c.635C>G p.S212* (on ENST00000625842 / NM_001349294.1; = p.S210* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV54993523, COSV99802338; called by muse, mutect2, varscan2
- VWA8 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1166488020, COSV55701410; called by muse, mutect2, varscan2
- WASF1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55620514; called by muse, mutect2, varscan2
- WDPCP | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55427193; called by muse, mutect2, varscan2
- WDR20 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54473906; called by muse, mutect2, varscan2
- WDR31 | c.396G>C p.L132F (on ENST00000374193 / NM_001006615.3; = p.L131F on NM_145241.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV59147152; called by muse, mutect2, varscan2
- WDR41 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1392417249, COSV56999738; called by muse, mutect2, varscan2
- WDR45B | c.852G>C p.W284C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1162683869, COSV66408907; called by muse, mutect2, varscan2
- WFDC8 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV51491186; called by muse, mutect2, varscan2
- WNK1 | c.3907C>A p.L1303I (on ENST00000315939 / NM_018979.4; = p.L1056I on NM_014823.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60040604; called by muse, mutect2, varscan2
- WNK1 | c.5753C>T p.S1918F (on ENST00000315939 / NM_018979.4; = p.S1670F on NM_014823.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV60040642; called by muse, mutect2, varscan2
- XIRP2 | c.191C>G p.S64C (on ENST00000628543; = p.S239C on NM_152381.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV54720306, COSV99739299; called by muse, mutect2, varscan2
- ZBTB21 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100177144; called by muse, mutect2, varscan2
- ZC2HC1C | c.1283C>A p.A428D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421270553, COSV53172985; called by muse, mutect2, varscan2
- ZC3H3 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52792608, COSV52792768; called by muse, mutect2, varscan2
- ZC3H7B | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV60963605; called by muse, mutect2, varscan2
- ZC3HC1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100315823; called by muse, mutect2, varscan2
- ZCCHC3 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV66643599; called by muse, mutect2, varscan2
332 further variants in this file (58 protein-altering or splice-affecting, 254 silent, 20 other) are not listed here.
